Somatic mutation profile of tumor specimen 0DVNXF from CCDI case PBCMYH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.8 years (1,021 days).
Specimen 0DVNXF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef18d9f8-90b8-4f1a-8e0f-0cfe697966dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVNYN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5e3b905-1747-4204-83ba-9116c9b9556c

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 1 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, 3'UTR 2, Intron 2, Frame Shift Del 2, 5'UTR 2, In Frame Del 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.3934C>T p.R1312* | Nonsense Mutation (SNP) | VAF 135/488 reads (28%) | catalogued as rs1555911075, CM151330, COSV54328581; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 85/117 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADNP2 | c.2768C>T p.T923M | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746433088; called by muse, mutect2, varscan2
- EPHB4 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.945); catalogued as rs141985925; called by muse, mutect2, varscan2
- HS3ST4 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); catalogued as rs1387862537; called by muse, varscan2
- LILRB1 | c.2024G>A p.R675Q (on ENST00000427581; = p.R624Q on NM_006669.6) | Missense Mutation (SNP) | VAF 7/209 reads (3%) | SIFT tolerated (0.81); PolyPhen benign (0.013); catalogued as rs753349590, COSV61116699; called by muse, mutect2
- PRSS2 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1052863399; called by muse, mutect2, varscan2
- SESN1 | c.590C>T p.A197V (on ENST00000356644 / NM_001199933.1; = p.A256V on NM_014454.3) | Missense Mutation (SNP) | VAF 124/506 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57421410; called by muse, mutect2, varscan2
- SLITRK1 | c.1988C>A p.S663Y | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65674498; called by muse, mutect2, varscan2
- ABCA5 | c.2618del p.F873Sfs*30 | Frame Shift Del (DEL) | VAF 218/635 reads (34%) | called by mutect2, varscan2
- CNMD | c.498A>T p.E166D | Missense Mutation (SNP) | VAF 100/532 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CPA6 | c.515G>C p.R172T | Missense Mutation (SNP) | VAF 217/950 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FBRS | c.1228del p.A410Lfs*76 (on ENST00000287468; = p.A930Lfs*76 on NM_001105079.3) | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, varscan2
- INTS3 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); called by mutect2, varscan2
- JADE3 | c.554A>G p.H185R | Missense Mutation (SNP) | VAF 157/197 reads (80%) | SIFT tolerated (0.11); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PLPPR3 | c.838_849del p.H280_G283del (on ENST00000520876 / NM_001270366.2; = p.H308_G311del on NM_024888.2) | In Frame Del (DEL) | VAF 26/38 reads (68%) | called by mutect2, varscan2
- ZNF540 | c.1410G>C p.K470N | Missense Mutation (SNP) | VAF 38/452 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2
- ZNF790 | c.1819C>A p.H607N | Missense Mutation (SNP) | VAF 204/569 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- RIMS4 | c.537A>T p.P179= | Silent (SNP) | VAF 22/354 reads (6%) | called by muse, mutect2
- B3GNT9 | c.-42C>A | 5'UTR (SNP) | VAF 3/21 reads (14%) | called by muse, varscan2
- DMWD | c.-31C>G | 5'UTR (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- EBF1 | c.*62G>C | 3'UTR (SNP) | VAF 136/357 reads (38%) | called by muse, mutect2, varscan2
- HNRNPA1 | c.132+61G>A | Intron (SNP) | VAF 37/84 reads (44%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92516C>A | Intron (SNP) | VAF 52/270 reads (19%) | catalogued as rs1243370744; called by muse, mutect2, varscan2
- SAYSD1 | c.*66G>T | 3'UTR (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
